Somatic mutation profile of tumor specimen TCGA-QU-A6IL-01A (aliquot TCGA-QU-A6IL-01A-11D-A31L-08) from TCGA case TCGA-QU-A6IL, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.9 years (23,710 days).
Specimen TCGA-QU-A6IL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 458333eb-c035-4654-8f1f-9483ae6a5c8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QU-A6IL-10A (Blood Derived Normal), aliquot TCGA-QU-A6IL-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ffee033-d25c-4ff3-91bb-1e87a5754085

The open-access MAF lists 33 somatic variants for this specimen: 19 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 15, Silent 14, Frame Shift Del 2, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.761_766del p.F254_N256delinsY | In Frame Del (DEL) | VAF 17/43 reads (40%) | hotspot (GDC flag); catalogued as COSV51644065; called by mutect2, pindel, varscan2
- C4orf51 | c.381G>T p.W127C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.785); catalogued as COSV71264074; called by muse, varscan2
- CDK10 | c.614G>A p.R205Q (on ENST00000353379 / NM_052988.5; = p.R134Q on NM_052987.4) | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1391347309, COSV104390117, COSV57048002; called by muse, mutect2
- CTNNAL1 | c.304A>G p.I102V | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV57704377; called by muse, mutect2, varscan2
- CUL3 | c.1676T>G p.L559R | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52367760; called by muse, mutect2, varscan2
- DDX60 | c.3638G>A p.C1213Y | Missense Mutation (SNP) | VAF 71/188 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV67098006; called by muse, mutect2, varscan2
- DISC1 | c.1666T>C p.S556P | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV54413276; called by muse, mutect2, varscan2
- GFAP | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53652139; called by muse, mutect2, varscan2
- HPS3 | c.2872C>A p.L958M | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52832389; called by muse, mutect2, varscan2
- MUC5AC | c.15043C>T p.R5015W | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as rs954182820, COSV100611342; called by muse, mutect2, varscan2
- NOTCH3 | c.5210C>T p.P1737L | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as COSV54642217; called by muse, mutect2, varscan2
- OR5M1 | c.616A>C p.N206H | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1046948352, COSV73202284; called by muse, mutect2, varscan2
- PHKB | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 71/155 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV54521977, COSV54528422; called by muse, mutect2, varscan2
- SCN5A | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs199473082, CM100643, COSV61121113; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- SPHKAP | c.5092G>T p.E1698* (on ENST00000392056 / NM_001142644.2; = p.E1669* on NM_030623.3) | Nonsense Mutation (SNP) | VAF 9/95 reads (9%) | catalogued as COSV60884792, COSV60888036; called by muse, mutect2
- ZNF573 | c.1193G>T p.G398V (on ENST00000536220 / NM_001172692.1; = p.G340V on NM_152360.3) | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.599); catalogued as COSV59826996; called by muse, mutect2, varscan2
- ZNF606 | c.1831C>G p.L611V | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV58707267; called by muse, mutect2, varscan2
- CADPS2 | c.531del p.F177Lfs*5 | Frame Shift Del (DEL) | VAF 14/25 reads (56%) | called by mutect2, pindel, varscan2
- PTGR1 | c.399_400del p.L134* | Frame Shift Del (DEL) | VAF 29/202 reads (14%) | called by mutect2, pindel, varscan2
- ARHGAP32 | c.2760A>G p.S920= (on ENST00000310343 / NM_001378025.1; = p.S571= on NM_014715.4) | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV59852463; called by muse, mutect2, varscan2
- ARHGEF10 | c.3571C>T p.L1191= (on ENST00000398564; = p.L1166= on NM_014629.4) | Silent (SNP) | VAF 42/58 reads (72%) | catalogued as COSV50663036; called by muse, mutect2, varscan2
- CACNA1B | c.729G>A p.E243= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV53138234; called by muse, mutect2, varscan2
- CHGB | c.1788C>T p.D596= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV66761274; called by muse, mutect2
- FRMPD1 | c.2346C>G p.G782= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV66701542; called by muse, mutect2, varscan2
- GKN2 | c.378G>C p.L126= | Silent (SNP) | VAF 89/200 reads (45%) | catalogued as COSV61031667; called by muse, mutect2, varscan2
- MTAP | c.498G>A p.K166= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as COSV66478061; called by muse, mutect2, varscan2
- NXPE3 | c.1047G>A p.E349= | Silent (SNP) | VAF 15/256 reads (6%) | catalogued as COSV56291242; called by muse, mutect2
- OR52D1 | c.519T>C p.G173= | Silent (SNP) | VAF 9/259 reads (3%) | catalogued as COSV59488021; called by muse, mutect2
- SIPA1L3 | c.3463C>A p.R1155= | Silent (SNP) | VAF 144/389 reads (37%) | catalogued as COSV55919846, COSV55924850; called by muse, mutect2, varscan2
- SULF2 | c.1824C>T p.N608= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as COSV63415168; called by muse, mutect2
- TRIM46 | c.153C>T p.N51= | Silent (SNP) | VAF 12/198 reads (6%) | catalogued as rs149212033; called by muse, mutect2
- WDR82 | c.192T>C p.Y64= | Silent (SNP) | VAF 25/256 reads (10%) | catalogued as rs558625924, COSV56602435; called by muse, mutect2
- ZNF780B | c.1818T>C p.F606= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV55466580, COSV55466655; called by muse, mutect2
